MMRF case MMRF_1572 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/6ae7886e-1d06-4e9b-a6f5-19c31c8ce024

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.8 years (25,141 days); ISS stage: II; Days to last known disease status: 1,275 days (3.5 years); Days to last follow up: 1,275 days (3.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 124 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 149 days; Days to treatment end: 149 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 150 days; Days to treatment end: 150 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 268 days; Days to treatment end: 270 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -12 (ECOG 1): M Protein 7.34 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.14 mg/dL; Immunoglobulin G 81.1 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 2.58 µg/mL; Lactate Dehydrogenase 1.18 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.54 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.5 mmol/L; Albumin 28 g/L; Total Protein 12 g/dL; Glucose 6.27 mmol/L; C-Reactive Protein 0.134 mg/dL.
- Day 64 (ECOG 1): M Protein 0.29 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.12 mg/dL; Immunoglobulin G 7.43 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 1.5 µg/mL; Lactate Dehydrogenase 2.1 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 51.3 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 4.84 mmol/L.
- Day 175 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 6.05 g/L; Immunoglobulin A 1.19 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 1.88 µg/mL; Lactate Dehydrogenase 1.78 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.24 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 49.5 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.5 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 5.61 mmol/L.
- Day 260 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.08 mg/dL; Immunoglobulin G 6.12 g/L; Immunoglobulin A 0.89 g/L; Immunoglobulin M 0.52 g/L; Beta 2 Microglobulin 1.47 µg/mL; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 9.3 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4.29 ×10⁹/L; Platelets 102 ×10⁹/L; Creatinine 46.9 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 5.78 mmol/L.
- Day 330: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.51 mg/dL; Immunoglobulin G 6.8 g/L; Immunoglobulin A 1.18 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 1.72 µg/mL; Lactate Dehydrogenase 1.67 µkat/L; Hemoglobin 9.55 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 108 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.48 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 5.5 mmol/L.
- Day 414: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.83 mg/dL; Immunoglobulin G 6.8 g/L; Immunoglobulin A 1.21 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 1.98 µg/mL; Lactate Dehydrogenase 4.22 µkat/L; Hemoglobin 9.61 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.45 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 6.77 mmol/L.
- Day 520: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 8.19 g/L; Immunoglobulin A 1.26 g/L; Immunoglobulin M 0.54 g/L; Beta 2 Microglobulin 1.83 µg/mL; Lactate Dehydrogenase 1.88 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.54 ×10⁹/L; Platelets 129 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.5 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 5.5 mmol/L.
- Day 582 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.92 mg/dL; Immunoglobulin G 6.49 g/L; Immunoglobulin A 1.31 g/L; Immunoglobulin M 0.36 g/L; Beta 2 Microglobulin 1.52 µg/mL; Lactate Dehydrogenase 3.62 µkat/L; Hemoglobin 9.3 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.43 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 5.23 mmol/L.
- Day 715 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.58 mg/dL; Immunoglobulin G 4.91 g/L; Immunoglobulin A 1.5 g/L; Immunoglobulin M 0.38 g/L; Beta 2 Microglobulin 1.5 µg/mL; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.43 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 5.45 mmol/L.
- Day 806 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.66 mg/dL; Immunoglobulin G 6.64 g/L; Immunoglobulin A 1.5 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 1.36 µg/mL; Lactate Dehydrogenase 3.75 µkat/L; Hemoglobin 9.92 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.55 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 5.61 mmol/L.
- Day 904 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.3 mg/dL; Immunoglobulin G 2.1 g/L; Immunoglobulin A 8.6 g/L; Immunoglobulin M 0.45 g/L; Beta 2 Microglobulin 1.52 µg/mL; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 9.92 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.5 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 6.66 mmol/L.
- Day 995 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.81 mg/dL; Immunoglobulin G 7.99 g/L; Immunoglobulin A 1.83 g/L; Immunoglobulin M 0.48 g/L; Beta 2 Microglobulin 1.12 µg/mL; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 10.2 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.45 mmol/L; Albumin 43 g/L; Total Protein 6.6 g/dL; Glucose 6.11 mmol/L.
- Day 1,079 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.87 mg/dL; Immunoglobulin G 2.45 g/L; Immunoglobulin A 7.35 g/L; Immunoglobulin M 0.45 g/L; Beta 2 Microglobulin 1.46 µg/mL; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 9.73 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.63 mmol/L; Albumin 45 g/L; Total Protein 7.2 g/dL; Glucose 5.17 mmol/L.
- Day 1,170 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.92 mg/dL; Immunoglobulin G 7.46 g/L; Immunoglobulin A 2.53 g/L; Immunoglobulin M 0.43 g/L; Beta 2 Microglobulin 1.32 µg/mL; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 9.86 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.65 mmol/L; Albumin 45 g/L; Total Protein 7.2 g/dL; Glucose 5.89 mmol/L.
- Day 1,275: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.97 mg/dL; Immunoglobulin G 7.75 g/L; Immunoglobulin A 2.76 g/L; Immunoglobulin M 0.4 g/L; Beta 2 Microglobulin 1.31 µg/mL; Lactate Dehydrogenase 2.13 µkat/L; Hemoglobin 9.61 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.25 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.63 mmol/L; Albumin 44 g/L; Total Protein 7.1 g/dL; Glucose 6.16 mmol/L.

Other clinical attributes
- Day -12: Weight: 92 kg; Height: 179 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Breast Cancer.

Biospecimens (2 samples)
- Sample MMRF_1572_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -12 days.
- Sample MMRF_1572_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -12 days.
